Somatic mutation profile of tumor specimen 0DEP1Q from CCDI case PBBRBI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.0 years (6,219 days).
Specimen 0DEP1Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ebeb8b3-b4ff-47f6-b072-7f18b2d25f6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEP1R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e69bcb-6b47-40ee-8162-49e3b825b06a

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 2, 5'UTR 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLITRK4 | c.2390del p.G797Afs*18 | Frame Shift Del (DEL) | VAF 260/896 reads (29%) | catalogued as COSV62026137; called by pindel, varscan2
- SPRY4 | c.520dup p.R174Pfs*40 (on ENST00000434127 / NM_001127496.3; = p.R197Pfs*40 on NM_030964.4) | Frame Shift Ins (INS) | VAF 145/507 reads (29%) | catalogued as rs774139814; called by pindel, varscan2
- TTN | c.20689A>G p.N6897D (on ENST00000591111; = p.N5970D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/464 reads (28%) | PolyPhen benign (0); catalogued as rs998292768; called by muse, varscan2
- GUCY2D | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 136/456 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, varscan2
- HNRNPM | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 156/480 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- LIPF | c.703_705del p.N235del | In Frame Del (DEL) | VAF 102/407 reads (25%) | called by pindel, varscan2
- CDCP1 | c.2106C>T p.P702= | Silent (SNP) | VAF 168/470 reads (36%) | catalogued as rs757938723; called by muse, varscan2
- MYORG | c.1713C>T p.R571= | Silent (SNP) | VAF 126/448 reads (28%) | called by muse, varscan2
- ZNF679 | c.1137C>G p.P379= | Silent (SNP) | VAF 68/206 reads (33%) | called by muse, varscan2
- BAG1 | c.-11C>A | 5'UTR (SNP) | VAF 126/316 reads (40%) | catalogued as rs1299923208; called by muse, varscan2
- CD58 | c.706+63dup | Intron (INS) | VAF 86/310 reads (28%) | called by pindel, varscan2
- LILRA5 | c.*41G>A | 3'UTR (SNP) | VAF 34/122 reads (28%) | called by muse, varscan2
- MAGEA12 | c.-11C>T | 5'UTR (SNP) | VAF 168/509 reads (33%) | called by muse, varscan2
- TRPM6 | c.33+162G>A | Intron (SNP) | VAF 123/434 reads (28%) | called by muse, varscan2
